MMRF case MMRF_2339 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d9a29ae3-2b22-4cca-8505-c059a28def8c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.7 years (19,611 days); ISS stage: I; Days to last known disease status: 773 days (2.1 years); Days to last follow up: 773 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 214 days; Days to treatment end: 214 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 4.37 g/L; Immunoglobulin A 34 g/L; Beta 2 Microglobulin 3.08 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 8.8 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.006 mg/dL.
- Day 99 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 5.21 g/L; Immunoglobulin A 7.42 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.9 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 180 (ECOG 0): Hemoglobin 7.19 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 378 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 275 (ECOG 1): Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 5.34 mmol/L.
- Day 381 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.706 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.196 mg/dL; Immunoglobulin G 2.84 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.37 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 336 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 444 (ECOG 0): M Protein 1.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 0.42 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 512: Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 4.05 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.28 mmol/L.
- Day 605 (ECOG 0): Hemoglobin 7.44 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 6.71 mmol/L.
- Day 689 (ECOG 0): Hemoglobin 7.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 773 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day 1: Weight: 62 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2339_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2339_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
